Gene-level copy-number profile of tumor specimen TCGA-S8-A6BV-01A from TCGA case TCGA-S8-A6BV, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 77.0 years (28,111 days).
Specimen TCGA-S8-A6BV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.df66ad60-26cd-483d-9ee8-cf1a7565118f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-S8-A6BV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b541d0d5-2511-418b-a5df-181e280627c6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 714; copy number 2: 21,928; copy number 3: 23,585; copy number 4: 9,692; copy number 5: 1,055; copy number 6: 823; copy number 7: 916; copy number 8: 640; copy number 9: 80; copy number 10: 104; copy number 12: 89; copy number 15: 25; copy number 18: 47; copy number 24: 94.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-S8-A6BV-01A-21D-A31T-01): tumor purity 0.41, ploidy 3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,214,672, 15 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,995 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,173,880–2,633,016, 89 genes, copy number 12 (within-gene range 3–12) (broad region; genes not listed).
- chr1:9,900,614–12,512,047, 94 genes, copy number 24 (within-gene range 3–24) (broad region; genes not listed).
- chr1:143,343,180–189,993,097, 1,368 genes, copy number 7–18 (broad region; genes not listed).
- chr1:245,749,342–248,919,946, 136 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr2:189,879,609–190,203,484, 1 gene, copy number 7 (within-gene range 3–7): C2orf88.
- chr2:189,923,336–190,371,665, 5 genes, copy number 7 (within-gene range 5–7): HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1.
- chr2:198,299,276–199,476,935, 8 genes, copy number 7: LINC01923, AC019330.1, AC020718.1, AC018717.1, RNU7-147P, SATB2, AC016746.1, SATB2-AS1.
- chr2:206,114,817–208,129,828, 64 genes, copy number 8–15 (broad region; genes not listed).
- chr6:37,257,772–44,553,281, 205 genes, copy number 9–18 (within-gene range 4–18) (broad region; genes not listed).
- chr14:36,647,083–38,606,098, 25 genes, copy number 7 (within-gene range 5–7): AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1, AL357094.1.

Autosomal genes at a single copy (total copy number 1): 680. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
